FM case AD3858 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/a92e9810-002d-4941-a576-810ae18617fc

Female, 44.9 years: Duct adenocarcinoma, NOS (ICD-O-3 8500/3) of the pancreas; primary biopsied or resected from the pancreas. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
